CCDI case PBCBHR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5e971606-4a6c-4ed0-ae12-0f0610fcd93f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,118 days).

Biospecimens (3 samples)
- Sample 0DN62Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN63E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DN63V: Tissue type: Tumor; Specimen type: Solid Tissue.
